Somatic mutation profile of tumor specimen MMRF_2716_1_BM_CD138pos (aliquot MMRF_2716_1_BM_CD138pos_T1_KHS5U_L14836) from MMRF case MMRF_2716, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2716_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8839d07b-6570-4c43-b22b-74facc0be149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2716_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2716_1_PB_WBC_C2_KHS5U_L14838; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8ab9cb0-654d-4379-86ec-a292ed5e10d5

The open-access MAF lists 109 somatic variants for this specimen: 29 protein-altering or splice-affecting, 15 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 27, Intron 15, Silent 15, 5'UTR 7, RNA 3, 3'Flank 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 32/159 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ASTN1 | c.2587G>A p.G863S | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368166205, COSV56083624; called by muse, mutect2, varscan2
- CASZ1 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs747304331, COSV65455655; called by muse, mutect2, varscan2
- CDH16 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs1235201138; called by muse, mutect2, varscan2
- CSMD1 | c.9854C>T p.A3285V (on ENST00000520002; = p.A3284V on NM_033225.6) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.993); catalogued as rs534317062, COSV100154046; called by muse, mutect2, varscan2
- IGHJ3 | c.8T>G p.F3C | Missense Mutation (SNP) | VAF 36/53 reads (68%) | PolyPhen probably damaging (0.919); catalogued as rs372359611; called by muse, varscan2
- IGHV2-70 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs369201986; called by muse, varscan2
- JAK1 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.985); catalogued as rs763612181; called by muse, mutect2, varscan2
- MAPK10 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | catalogued as rs746905703; called by muse, mutect2, varscan2
- MRPS18B | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 146/235 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs778603898; called by muse, mutect2, varscan2
- NDST4 | c.2081T>C p.I694T | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as rs140851859; called by muse, mutect2, varscan2
- NLRP8 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs777710675, COSV52587041; called by muse, mutect2, varscan2
- RC3H1 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51199722; called by muse, mutect2, varscan2
- SLC16A14 | c.1394A>T p.D465V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54617938; called by muse, mutect2, varscan2
- TTN | c.14380G>T p.D4794Y (on ENST00000591111; = p.D3867Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/204 reads (6%) | PolyPhen possibly damaging (0.891); catalogued as COSV59997180, COSV60060818; called by muse, mutect2
- ZMAT5 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs762345075; called by muse, mutect2, varscan2
- ZNF234 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs751143324; called by muse, mutect2
- C1orf167 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CIART | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 84/436 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- FCHO2 | c.2251G>A p.G751R | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FNDC1 | c.3652A>G p.S1218G | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); called by muse, mutect2
- GARS1 | c.658+7T>C | Splice Region (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 102/158 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, varscan2
- KIZ | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- MCMBP | c.1628T>G p.V543G | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MRPL44 | c.812T>A p.F271Y | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ODF2 | c.1471G>C p.V491L (on ENST00000434106 / NM_153433.2; = p.V467L on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHKG1 | c.964T>C p.Y322H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- VWA1 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- CLCN2 | c.759G>C p.A253= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2, varscan2
- CPXM1 | c.2064C>A p.T688= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV66046656; called by muse, mutect2
- FBLN5 | c.747C>T p.D249= | Silent (SNP) | VAF 66/129 reads (51%) | catalogued as rs554422450, COSV50904377, COSV50906475; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGKV1-5 | c.264A>T p.G88= | Silent (SNP) | VAF 112/150 reads (75%) | catalogued as rs571455973; called by muse, varscan2
- IGKV1-5 | c.157_159delinsTCT p.S53= | Silent (TNP) | VAF 17/33 reads (52%) | called by pindel, varscan2*
- IGKV1-5 | c.93C>T p.S31= | Silent (SNP) | VAF 54/172 reads (31%) | catalogued as rs536971237; called by muse, varscan2
- ITIH6 | c.1536C>A p.G512= | Silent (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- KBTBD13 | c.969C>T p.Y323= | Silent (SNP) | VAF 13/206 reads (6%) | catalogued as rs568613948, COSV71351377; called by muse, mutect2
- LAS1L | c.1779G>A p.E593= | Silent (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- MAGEB6 | c.90C>A p.A30= | Silent (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
- PRSS41 | c.78G>A p.A26= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs778715609; called by muse, mutect2, varscan2
- PTGDR | c.324C>T p.F108= | Silent (SNP) | VAF 42/303 reads (14%) | catalogued as rs1210877590, COSV100035608; called by muse, mutect2, varscan2
- SPEG | c.2955G>A p.A985= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs569559304; called by muse, mutect2, varscan2
- TRO | c.2646G>A p.A882= | Silent (SNP) | VAF 101/195 reads (52%) | catalogued as rs1314416748; called by muse, mutect2, varscan2
- VWA8 | c.3081C>T p.I1027= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as rs374661992; called by muse, mutect2, varscan2
- AADACL3 | c.*315G>A | 3'UTR (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- AC034198.1 | n.46A>G | RNA (SNP) | VAF 26/223 reads (12%) | catalogued as rs755439054; called by muse, mutect2, varscan2
- AC068631.2 | chr3:186597162 C>T | 3'Flank (SNP) | VAF 10/96 reads (10%) | catalogued as rs891122760; called by muse, mutect2, varscan2
- ADAM28 | c.1567+345T>C | Intron (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- AHRR | c.*2359A>C | 3'UTR (SNP) | VAF 34/49 reads (69%) | called by muse, mutect2, varscan2
- ANOS1 | c.*447C>T | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*2836A>G | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- ATG14 | c.*2880A>C | 3'UTR (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- C5orf66-AS2 | n.1419C>T | RNA (SNP) | VAF 60/104 reads (58%) | called by muse, mutect2
- CALN1 | c.*701A>T | 3'UTR (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- CLK3 | c.814-177C>T | Intron (SNP) | VAF 35/566 reads (6%) | called by muse, mutect2
- CPEB4 | c.*470T>C | 3'UTR (SNP) | VAF 23/74 reads (31%) | catalogued as rs1056702040; called by mutect2, varscan2
- DDI1 | c.*357dup | 3'UTR (INS) | VAF 44/104 reads (42%) | catalogued as rs1308133861; called by mutect2, pindel, varscan2
- DPPA4 | c.178+98T>G | Intron (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2
- EFR3B | c.2142+189G>T | Intron (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- FAM220A | c.*237A>C | 3'UTR (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- FAU | c.276+42T>C | Intron (SNP) | VAF 15/335 reads (4%) | called by muse, mutect2
- FBN2 | c.*555G>A | 3'UTR (SNP) | VAF 18/73 reads (25%) | catalogued as rs1372593754; called by muse, mutect2, varscan2
- GLDN | c.364-155C>T | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- GMPS | c.*914A>G | 3'UTR (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- GPR107 | c.*4221T>C | 3'UTR (SNP) | VAF 19/189 reads (10%) | called by muse, mutect2, varscan2
- GPRASP1 | c.*286C>T | 3'UTR (SNP) | VAF 8/44 reads (18%) | catalogued as rs1185386558; called by muse, mutect2, varscan2
- GREM2 | c.*1349C>A | 3'UTR (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- GREM2 | c.*1348T>A | 3'UTR (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- GRK6 | c.*243G>A | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- HEPH | c.*76C>A | 3'UTR (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- HEPH | c.*77C>G | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.*344C>T | 3'UTR (SNP) | VAF 15/86 reads (17%) | catalogued as rs1242907791; called by muse, mutect2, varscan2
- IGIP | c.-944C>T | 5'UTR (SNP) | VAF 19/115 reads (17%) | catalogued as COSV100322924; called by muse, mutect2, varscan2
- IQGAP2 | c.-221A>C | 5'UTR (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- KCNMB3P1 | n.2742A>G | RNA (SNP) | VAF 12/109 reads (11%) | catalogued as rs974433816; called by muse, mutect2, varscan2
- KDM8 | c.*652G>T | 3'UTR (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- KLF4 | c.*110C>T | 3'UTR (SNP) | VAF 9/88 reads (10%) | catalogued as rs1000570841; called by muse, mutect2
- MAD1L1 | c.1074-10581A>G | Intron (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- MCF2L | c.369-436T>G | Intron (SNP) | VAF 41/189 reads (22%) | called by muse, mutect2, varscan2
- MRPL22 | c.-7G>A | 5'UTR (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- NGEF | c.*456G>A | 3'UTR (SNP) | VAF 97/293 reads (33%) | catalogued as rs1474276507; called by muse, mutect2, varscan2
- NRXN1 | c.832+2002T>G | Intron (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- NTRK2 | c.1585+6450G>T | Intron (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- NTRK3 | c.2133+12639G>A | Intron (SNP) | VAF 146/741 reads (20%) | called by muse, mutect2, varscan2
- OTUD5 | c.-12G>A | 5'UTR (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- PACRGL | c.*56+1970C>G | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- PCDH19 | c.-1306C>T | 5'UTR (SNP) | VAF 80/386 reads (21%) | called by muse, varscan2
- PHACTR2 | c.*5492A>G | 3'UTR (SNP) | VAF 20/32 reads (63%) | called by muse, varscan2
- PHACTR2 | c.*5590A>T | 3'UTR (SNP) | VAF 68/108 reads (63%) | called by muse, varscan2
- PHACTR2 | c.*5660A>C | 3'UTR (SNP) | VAF 76/113 reads (67%) | called by muse, varscan2
- PNMA5 | c.*394G>T | 3'UTR (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*6474C>G | 3'UTR (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- PRSS12 | c.*1557_*1559delinsG | 3'UTR (DEL) | VAF 9/41 reads (22%) | called by pindel, varscan2*
- RBM12B | c.-78+507T>G | Intron (SNP) | VAF 137/262 reads (52%) | called by muse, mutect2, varscan2
- RUNDC3B | c.*735A>G | 3'UTR (SNP) | VAF 52/97 reads (54%) | called by muse, mutect2, varscan2
- SBK1 | c.*301C>T | 3'UTR (SNP) | VAF 6/59 reads (10%) | catalogued as rs1331424231; called by muse, varscan2
- SEC16A | c.6698-33G>A | Intron (SNP) | VAF 229/367 reads (62%) | catalogued as rs762757544; called by muse, mutect2, varscan2
- SEC22A | chr3:123274133 G>A | 3'Flank (SNP) | VAF 10/34 reads (29%) | catalogued as rs1402768483; called by muse, mutect2, varscan2
- SHC1 | c.*1504T>C | 3'UTR (SNP) | VAF 81/117 reads (69%) | called by muse, mutect2, varscan2
- SOCS2 | c.140-215del | Intron (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- SYPL2 | c.*2393C>T | 3'UTR (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.*1069C>T | 3'UTR (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- TMEM168 | c.-23G>A | 5'UTR (SNP) | VAF 40/378 reads (11%) | catalogued as rs1298930414; called by muse, mutect2
- TMEM192 | c.*1066C>T | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- TMEM245 | c.*2595C>G | 3'UTR (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2, varscan2
- TMEM47 | c.-41G>T | 5'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.*457G>A | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- TRIM58 | c.*618C>A | 3'UTR (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- XRCC3 | c.*653G>A | 3'UTR (SNP) | VAF 75/160 reads (47%) | catalogued as rs1357350035; called by muse, mutect2, varscan2
